Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7R3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7R3-01A (Primary Tumor).

ICC-O-3
Astrocytoma, grade II 9400/3
Site ^{CASE} Brain, supratentorial NOS
~~Path~~ Brain NOS C71.0
C71.9
9/27/13

diffuse astrocytoma WHO grade II

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 322fedb7-6c65-4d37-b451-8eb353511925 (TCGA-S9-A7R3.769B080E-C2D2-492E-9B82-89BB55627F2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).